Gene-level copy-number profile of tumor specimen REBC-AF8S-TTP1 from REBC case REBC-AF8S, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF8S-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 540c1a54-26e7-4c0f-a6be-005cc3880f9d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF8S-NB1-SC217013 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/c8c15378-89b8-4d7a-b0f7-61f42a55fdeb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 165; copy number 2: 57,875; copy number 3: 350.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:65,189,995–65,193,610, 1 gene: BMS1P12.
- chr16:35,912,120–35,912,516, 1 gene: PPP1R1AP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
